Gene-level copy-number profile of tumor specimen TCGA-AA-A02R-01A from TCGA case TCGA-AA-A02R, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.4 years (30,834 days).
Specimen TCGA-AA-A02R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.57b31ff8-bd42-47d3-b560-0d5c18c571c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A02R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d6401c2d-39a1-4d99-8fa5-e0b9eb0d910b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 359; copy number 2: 56,310; copy number 3: 3,049.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A02R-01A-01D-A008-01): tumor purity 0.66, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:100,538,139–100,542,021, 1 gene: GPR88.
- chr1:109,504,178–109,509,738, 1 gene: AMIGO1.
- chr1:119,619,377–119,648,266, 1 gene: ZNF697.
- chr2:23,375,229–23,381,299, 1 gene: AC012506.4.
- chr2:213,152,970–213,167,712, 2 genes (within-gene range 0–2): AC079610.1, LINC01953.
- chr2:236,194,872–236,264,409, 2 genes (within-gene range 0–2): ASB18, RNU1-31P.
- chr2:237,612,977–237,626,525, 1 gene: AC104667.1.
- chr3:71,675,414–71,786,425, 4 genes (within-gene range 0–2): EIF4E3, GPR27, PROK2, AC096970.1.
- chr3:175,079,307–175,115,242, 1 gene (within-gene range 0–2): NAALADL2-AS3.
- chr3:183,815,922–183,825,594, 1 gene: MAP6D1.
- chr4:186,069,155–186,172,667, 3 genes (within-gene range 0–2): TLR3, FAM149A, AC104070.1.
- chr5:73,444,827–73,453,395, 3 genes: FOXD1, FOXD1-AS1, LINC01385.
- chr7:6,615,610–6,708,901, 4 genes (within-gene range 0–2): ZNF853, ZNF316, AC073343.2, AC073343.1.
- chr10:81,870,778–81,875,133, 1 gene: AL096706.1.
- chr10:91,152,605–91,161,315, 2 genes: NUDT9P1, AL731553.1.
- chr10:99,526,350–99,536,524, 3 genes: LINC01475, AL513542.1, NKX2-3.
- chr11:6,603,642–6,658,396, 10 genes: AC091564.2, ILK, TAF10, AC091564.3, AC091564.7, TPP1, AC091564.6, DCHS1, AC091564.4, AC091564.5.
- chr11:23,403,805–23,406,103, 1 gene: WIZP1.
- chr11:74,738,478–74,746,114, 2 genes: AP001324.2, AP001324.1.
- chr11:121,361,854–121,362,865, 1 gene: BMPR1AP2.
- chr11:130,002,938–130,033,220, 3 genes: LINC00167, AP003041.1, ELOBP2.
- chr12:94,140,077–94,141,337, 1 gene: AC123567.1.
- chr14:74,614,693–74,616,647, 1 gene: AC013451.2.
- chr14:95,533,355–95,544,724, 2 genes (within-gene range 0–2): SCARNA13, GLRX5.
- chr14:99,604,556–99,625,740, 1 gene (within-gene range 0–2): AL160313.1.
- chr15:79,559,256–79,560,304, 1 gene: TFDP1P3.
- chr15:100,861,924–100,919,391, 4 genes (within-gene range 0–2): AC015712.5, ALDH1A3, AC015712.7, AC015712.2.
- chr15:101,495,052–101,495,567, 1 gene: AC090164.2.
- chr17:32,258,615–32,265,404, 1 gene: AC026620.2.
- chr17:46,193,576–46,268,694, 5 genes: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.
- chr18:5,289,019–5,297,053, 1 gene: ZBTB14.
- chr19:33,360,497–33,382,686, 2 genes: AKR1B1P7, CEBPG.
- chr20:603,797–675,802, 4 genes: TCF15, SRXN1, AL121758.1, SCRT2.
- chr20:58,218,495–58,228,653, 1 gene (within-gene range 0–2): ANKRD60.
- chr21:39,313,935–39,349,647, 4 genes: BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA.
- chr22:17,116,297–17,132,104, 2 genes: TMEM121B, LINC01664.
- chr22:45,000,565–45,003,619, 1 gene: AL079301.1.
- chr22:46,255,663–46,263,343, 1 gene: PKDREJ.
- chr22:50,092,745–50,096,437, 1 gene: AL034546.1.
- chr22:50,669,804–50,801,309, 10 genes: Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 238. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
